MMRF case MMRF_1129 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a09931b7-0caa-4c44-a082-3ba3462f09fb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Dead; Days to death: 610 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.1 years (29,630 days); ISS stage: I; Days to last known disease status: 610 days (1.7 years); Days to last follow up: 610 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 211 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 256 days; Days to treatment end: 611 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 610.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 6.66 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 4.9 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 81 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Hemoglobin 6.88 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.51 mmol/L.
- Day 185 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 5.34 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.
- Day 256: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.878 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 6.29 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 394 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.
- Day 456 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 6.71 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 548 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.924 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.5 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day 1: Weight: 92 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1129_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1129_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
